Somatic mutation profile of tumor specimen TCGA-EY-A1GC-01A (aliquot TCGA-EY-A1GC-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.0 years (22,656 days).
Specimen TCGA-EY-A1GC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d5dcde7-6f21-4884-9512-5b91057f9adb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GC-10A (Blood Derived Normal), aliquot TCGA-EY-A1GC-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b1e5958-3250-4cbd-b153-d2bb9cc26f3f

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 24, Silent 13, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 44/61 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 26/41 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1G1 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100250551; called by muse, mutect2, varscan2
- ATM | c.7876G>A p.A2626T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99589980; called by muse, mutect2, varscan2
- BTNL3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as rs559517221, COSV61565164; called by muse, mutect2, varscan2
- DCC | c.3158A>T p.D1053V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100500562; called by muse, mutect2, varscan2
- DOCK11 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV99354027; called by muse, mutect2, varscan2
- ELMO1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs554916711, COSV60326702; called by muse, mutect2
- GTF2IRD1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587749109, COSV56084334; called by muse, mutect2
- HK3 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 64/141 reads (45%) | catalogued as rs573086536, COSV52836822; called by muse, mutect2, varscan2
- IFNA5 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 75/208 reads (36%) | catalogued as COSV99423699; called by muse, mutect2, varscan2
- KPNA6 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs781088395, COSV101012531; called by muse, mutect2, varscan2
- NCDN | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1347739249, COSV61935751, COSV61936638; called by muse, mutect2, varscan2
- PCDHGB1 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775400971, COSV53947801; called by muse, mutect2, varscan2
- PKNOX1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as rs1410401588, COSV99372902; called by muse, mutect2, varscan2
- RPS6KA6 | c.327dup p.A110Sfs*36 | Frame Shift Ins (INS) | VAF 30/105 reads (29%) | catalogued as rs756096568; called by mutect2, varscan2
- SAMD7 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV100156959; called by muse, mutect2
- SLC17A4 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1312889023, COSV100930606; called by muse, mutect2, varscan2
- SPTBN1 | c.6937G>A p.V2313M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV100777199; called by muse, mutect2, varscan2
- TAF1 | c.1712A>G p.H571R (on ENST00000373790 / NM_138923.4; = p.H592R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52120122; called by muse, mutect2, varscan2
- TDRD1 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs576653939, COSV52591672; called by muse, mutect2, varscan2
- ULK3 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs377255351; called by muse, mutect2, varscan2
- ZDHHC23 | c.1175A>T p.K392M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100362173; called by muse, mutect2, varscan2
- ZFC3H1 | c.4015T>A p.Y1339N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101110586; called by muse, mutect2, varscan2
- ZMYM3 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100077984; called by muse, mutect2, varscan2
- ZNF775 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs759823235, COSV61614260; called by muse, mutect2, varscan2
- FOXA2 | c.405dup p.M136Hfs*103 (on ENST00000377115 / NM_153675.3; = p.M142Hfs*103 on NM_021784.5) | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- GTF2IRD2 | c.1819T>G p.C607G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, varscan2
- STING1 | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.229); called by muse, mutect2
- CNTNAP1 | c.816C>G p.G272= | Silent (SNP) | VAF 21/183 reads (11%) | catalogued as COSV52851356, COSV99226557; called by muse, mutect2, varscan2
- COL23A1 | c.321G>C p.R107= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV101179012; called by muse, mutect2, varscan2
- GALNT18 | c.369C>T p.N123= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs764261840, COSV57158621; called by muse, mutect2, varscan2
- LDLR | c.531G>A p.S177= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs555158224, COSV52942899; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- LTA | c.315C>T p.G105= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV69304278; called by muse, mutect2, varscan2
- MTERF3 | c.387G>A p.E129= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99749826; called by muse, mutect2
- NUAK2 | c.1104G>C p.L368= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100904082; called by muse, mutect2, varscan2
- PALLD | c.2025C>T p.G675= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99824957; called by muse, mutect2, varscan2
- PCDHB3 | c.2130G>A p.A710= | Silent (SNP) | VAF 85/279 reads (30%) | catalogued as rs531712675, COSV50577138; called by muse, mutect2, varscan2
- PCDHGB7 | c.1506G>A p.S502= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV53922315; called by muse, mutect2, varscan2
- SKIL | c.1641G>A p.L547= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99378328; called by muse, mutect2, varscan2
- TRAV26-2 | c.33A>T p.L11= | Silent (SNP) | VAF 96/136 reads (71%) | called by muse, mutect2, varscan2
- TRIML1 | c.1149C>T p.I383= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs758081985, COSV60193621; called by muse, mutect2
